Gene-level copy-number profile of tumor specimen TCGA-2Z-A9JI-01A from TCGA case TCGA-2Z-A9JI, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 38.9 years (14,196 days).
Specimen TCGA-2Z-A9JI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.3c9b65bf-34e0-4582-9ff7-cd83516f4323.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2Z-A9JI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c47df9d9-27ef-4c8e-ad5a-5b8498c862e4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,208; copy number 2: 26,385; copy number 3: 8,077; copy number 4: 21,218; copy number 5: 1,217; copy number 6: 569; copy number 7: 69; copy number 8: 68; copy number 9: 1; copy number 10: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2Z-A9JI-01A-11D-A42I-01): tumor purity 0.43, ploidy 1.63, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,925 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:17,877,847–23,360,376, 73 genes, copy number 5 (broad region; genes not listed).
- chr2:58,427,799–59,063,766, 1 gene, copy number 5 (within-gene range 3–5): LINC01122.
- chr2:59,014,354–60,100,200, 10 genes, copy number 5: AC007092.1, LINC01793, AC007100.1, AC007179.2, AC007179.1, AC007179.3, RNU6-508P, RNA5SP94, AC007100.2, AC007132.1.
- chr3:188,947,214–189,325,304, 1 gene, copy number 5 (within-gene range 4–5): TPRG1.
- chr3:189,238,686–189,240,594, 1 gene, copy number 5: TPRG1-AS2.
- chr3:189,645,327–189,645,466, 1 gene, copy number 5: AC078809.1.
- chr5:142,716,229–156,852,528, 232 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:43,539,137–46,951,850, 23 genes, copy number 8 (within-gene range 4–8): AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1, AC118650.1, HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, AC021451.2, AC021451.3, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2.
- chr8:139,508,701–139,508,971, 1 gene, copy number 9: AC090093.1.
- chr12:114,104,542–114,105,931, 1 gene, copy number 10: GLULP5.
- chr17:32,258,615–57,745,299, 993 genes, copy number 5–7 (broad region; genes not listed).
- chr17:61,590,421–80,149,798, 543 genes, copy number 6–8 (broad region; genes not listed).
- chr20:39,213,777–43,304,679, 45 genes, copy number 5: LINC01734, AL035251.1, ATG3P1, RN7SL680P, AL132981.1, AL118523.1, HSPE1P1, LINC01370, AL133419.1, AL009050.1, MAFB, AL035665.1, AL035665.2, RNA5SP484, RNU2-52P, TOP1, PLCG1-AS1, PLCG1, MIR6871, ZHX3, AL022394.1, RPL23AP81, RN7SL615P, ADI1P1, LPIN3, EMILIN3, AL031667.1, CHD6, AL031667.2, AL031667.3, RPL12P11, RNU6-1018P, AL133229.1, AL049812.2, AL049812.1, AL049812.3, PTPRT, AL035666.1, AL031656.1, PTPRT-AS1, RN7SKP100, AL021395.1, RN7SL666P, PPIAP21, AL021395.2.

Autosomal genes at a single copy (total copy number 1): 2,208. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
